Somatic mutation profile of tumor specimen TCGA-G2-A2EF-01A (aliquot TCGA-G2-A2EF-01A-12D-A18F-08) from TCGA case TCGA-G2-A2EF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 50.6 years (18,467 days).
Specimen TCGA-G2-A2EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b4c6153-f7a8-4c25-adce-0671e7a81406.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2EF-10A (Blood Derived Normal), aliquot TCGA-G2-A2EF-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd6d3133-febe-40be-b261-3b9b2fbad186

The open-access MAF lists 283 somatic variants for this specimen: 206 protein-altering or splice-affecting, 68 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 68, Nonsense Mutation 15, Frame Shift Del 7, Intron 4, Splice Site 3, 3'UTR 3, Translation Start Site 2, Frame Shift Ins 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPG2 | c.7006+1G>A p.X2336_splice | Splice Site (SNP) | VAF 37/80 reads (46%) | catalogued as rs778653296, CS065567, COSV65970478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/183 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 147/213 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV59247480; called by muse, mutect2, varscan2
- ADAMTS10 | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368873893, COSV54353379; called by muse, varscan2
- ADAMTS10 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1555738275, COSV54353387; called by muse, varscan2
- ADAMTS5 | c.2762C>G p.A921G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV53177665; called by muse, mutect2, varscan2
- ADGRV1 | c.12973G>C p.E4325Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as COSV67982674; called by muse, mutect2, varscan2
- AGL | c.4579G>C p.E1527Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV54050953; called by muse, mutect2, varscan2
- AKAP9 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV62342928; called by muse, mutect2, varscan2
- ALOXE3 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs767851457, COSV59074941, COSV59078620; called by muse, mutect2, varscan2
- APPL2 | c.1719G>C p.K573N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as COSV51588037, COSV51589445; called by muse, mutect2, varscan2
- ARHGAP33 | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV50121216, COSV99139436; called by muse, mutect2, varscan2
- ARHGEF7 | c.1711G>C p.E571Q (on ENST00000375741 / NM_001113511.2; = p.E393Q on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as COSV54541476; called by muse, mutect2, varscan2
- ASPM | c.7869A>C p.E2623D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.342); catalogued as COSV54127924; called by muse, mutect2, varscan2
- AVL9 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs774417716, COSV59464961; called by muse, mutect2, varscan2
- BIRC6 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as COSV70197606; called by muse, mutect2, varscan2
- BNIP3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs377253213; called by muse, mutect2, varscan2
- BOC | c.2050C>G p.L684V | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56349119; called by muse, mutect2, varscan2
- BTN1A1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55067157; called by muse, mutect2, varscan2
- CACNB1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1204093375, COSV59998519; called by muse, mutect2, varscan2
- CAP1 | c.1371C>G p.F457L | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV61223136; called by muse, mutect2, varscan2
- CAPS2 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 23/133 reads (17%) | catalogued as rs777691317; called by muse, mutect2, varscan2
- CASKIN2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372950574; called by muse, mutect2, varscan2
- CBX4 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 84/202 reads (42%) | catalogued as rs752098519; called by muse, mutect2, varscan2
- CCDC38 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV60182140, COSV60182721; called by muse, mutect2
- CCND3 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.207); catalogued as COSV65912508, COSV65912902; called by muse, mutect2, varscan2
- CCT5 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54723515; called by muse, mutect2, varscan2
- CCZ1B | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.243); catalogued as COSV51868529; called by muse, mutect2, varscan2
- CD1A | c.913T>G p.L305V | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV56861109; called by muse, mutect2, varscan2
- CDC27 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50372755; called by muse, mutect2, varscan2
- CEACAM8 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV54990516; called by muse, mutect2, varscan2
- CERKL | c.540A>T p.K180N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59205794; called by muse, mutect2, varscan2
- CGGBP1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as COSV58851651; called by muse, mutect2, varscan2
- CIP2A | c.2538G>C p.L846F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55418040; called by muse, mutect2, varscan2
- CIR1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV59595621, COSV59597966; called by muse, mutect2, varscan2
- CNOT6 | c.1465A>C p.I489L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV56160775; called by muse, varscan2
- COG8 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs372024004; called by muse, mutect2, varscan2
- CROT | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.033); catalogued as COSV58973655; called by muse, mutect2, varscan2
- CSMD2 | c.9754G>A p.G3252R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1182902224, COSV53899029, COSV53936910; called by muse, mutect2, varscan2
- CYFIP2 | c.3025G>A p.E1009K (on ENST00000616178 / NM_001291722.2; = p.E984K on NM_014376.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as COSV59033775; called by muse, mutect2, varscan2
- CYP1B1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as COSV53191083; called by muse, mutect2, varscan2
- CYP3A7 | c.671-2A>G p.X224_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | catalogued as rs745458588, COSV60481093; called by muse, mutect2, varscan2
- CYP46A1 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV55893912; called by muse, mutect2, varscan2
- DCAKD | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV60202023; called by muse, mutect2, varscan2
- DDX42 | c.2685G>C p.K895N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); catalogued as rs1029173162, COSV63789794; called by muse, mutect2, varscan2
- DENND4B | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV63408172; called by muse, mutect2, varscan2
- DENND4C | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV66821901; called by muse, mutect2, varscan2
- DIS3 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs754234020, COSV66705903; called by muse, mutect2, varscan2
- DOCK1 | c.4739G>A p.R1580K | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV54735414; called by muse, mutect2, varscan2
- DSP | c.6605C>T p.S2202L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101131360, COSV65792182; called by muse, mutect2, varscan2
- DST | c.5597C>G p.S1866C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55007230, COSV55018098; called by muse, mutect2, varscan2
- ECHDC3 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101004527; called by muse, mutect2, varscan2
- EIF2B5 | c.982C>T p.P328S (on ENST00000647909; = p.P320S on NM_003907.3) | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56604199; called by muse, mutect2, varscan2
- EIF4E1B | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV53779845; called by mutect2, varscan2
- ELMO2 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV51682353; called by muse, mutect2, varscan2
- EVI5L | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as rs754933940, COSV54484856; called by muse, mutect2, varscan2
- FAT3 | c.9118G>A p.E3040K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53095172; called by muse, mutect2, varscan2
- FAT4 | c.3969T>A p.D1323E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV67883794; called by muse, mutect2, varscan2
- FBH1 | c.1252A>T p.N418Y (on ENST00000362091 / NM_178150.3; = p.N469Y on NM_032807.4) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62982167; called by muse, mutect2
- FGD5 | c.2666G>A p.G889E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV53240254; called by muse, mutect2, varscan2
- FGD5 | c.3867G>A p.M1289I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.268); catalogued as rs781162883, COSV53240273; called by muse, mutect2, varscan2
- FLG | c.5527C>G p.H1843D | Missense Mutation (SNP) | VAF 211/448 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs752844608, COSV100912141, COSV64239786; called by muse, mutect2, varscan2
- FLRT3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755488912, COSV53963663, COSV99427843; called by muse, mutect2, varscan2
- FOXB2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65022762; called by muse, varscan2
- FRAS1 | c.5415C>G p.F1805L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.8); catalogued as COSV53601773; called by muse, mutect2, varscan2
- FZD7 | c.1380G>C p.K460N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV53808939; called by muse, mutect2, varscan2
- GAS2 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV53406266; called by muse, mutect2, varscan2
- GAS2L3 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 81/146 reads (55%) | catalogued as COSV57157261; called by muse, mutect2, varscan2
- GCC2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV59180095; called by muse, mutect2, varscan2
- GIGYF1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51940596; called by muse, mutect2, varscan2
- GOLPH3L | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55045654; called by muse, mutect2, varscan2
- GOLPH3L | c.562C>A p.H188N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55045681; called by muse, mutect2, varscan2
- H3C2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV52518070, COSV52519869; called by muse, mutect2, varscan2
- HACE1 | c.2271C>G p.I757M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV53501319, COSV53503257; called by muse, mutect2, varscan2
- HCN3 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1012383857, COSV61360852; called by muse, mutect2, varscan2
- HLA-DQA2 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV66564953; called by muse, mutect2, varscan2
- HRH1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV67955289; called by muse, mutect2, varscan2
- HSCB | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53262170, COSV53263382; called by muse, mutect2, varscan2
- HSPA1A | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65148954; called by muse, mutect2, varscan2
- IGSF9 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1042907959, COSV63639034, COSV63639533; called by muse, mutect2, varscan2
- INSM2 | c.1550C>G p.S517C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as rs1418777965, COSV51880145; called by muse, mutect2, varscan2
- ITCH | c.719C>G p.S240C (on ENST00000262650 / NM_001257137.3; = p.S199C on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52930902; called by muse, mutect2, varscan2
- KATNA1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV59502020; called by muse, mutect2, varscan2
- KMT2C | c.8392G>T p.E2798* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV100068632; called by mutect2, varscan2
- KMT2D | c.1570del p.E524Kfs*406 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as COSV56445560; called by mutect2, pindel, varscan2
- LPIN2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs941401458, COSV55238773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1 | c.6745C>T p.P2249S | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54506947; called by muse, mutect2, varscan2
- LRP1B | c.13495G>A p.E4499K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67203105; called by muse, mutect2
- LRRTM3 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV63662133; called by muse, mutect2, varscan2
- LRTM2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs527284344, COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- LSG1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV54569347; called by muse, mutect2, varscan2
- LYSMD1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV54860071; called by muse, mutect2, varscan2
- MAML3 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs767115747, COSV72208860; called by muse, mutect2, varscan2
- MCF2L2 | c.1372C>G p.R458G | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs754136583, COSV61051636; called by muse, mutect2
- MED1 | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV56123724; called by muse, mutect2, varscan2
- MED1 | c.3653C>G p.S1218C | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV56123736; called by muse, mutect2, varscan2
- MROH7 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV59870363; called by muse, mutect2, varscan2
- MST1 | c.1772C>A p.S591Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV56533003; called by muse, mutect2, varscan2
- MTIF2 | c.1921G>T p.V641F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV55050945; called by muse, mutect2, varscan2
- MUC16 | c.27217G>A p.E9073K | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV67457150; called by muse, mutect2, varscan2
- MUC3A | c.8608G>A p.E2870K | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.065); catalogued as COSV60213402, COSV60221960; called by muse, mutect2, varscan2
- MYO5B | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53215547; called by muse, mutect2, varscan2
- NLRP3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.053); catalogued as rs768966147, COSV60222235; called by muse, mutect2, varscan2
- NME1-NME2 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | catalogued as rs376345325; called by muse, mutect2, varscan2
- NMT2 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746938697, COSV65381908; called by muse, mutect2, varscan2
- NOC2L | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV58531338, COSV58533387; called by muse, mutect2, varscan2
- NOP56 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61389542; called by muse, mutect2, varscan2
- NOX4 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 123/176 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54450526; called by muse, mutect2, varscan2
- NRXN1 | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV60489483, COSV60492415; called by muse, mutect2, varscan2
- OBSCN | c.14746C>T p.R4916W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs199529556, COSV52742151; called by muse, mutect2, varscan2
- OGFRL1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); catalogued as rs1174728040, COSV100965761, COSV64971795; called by muse, mutect2, varscan2
- OLA1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as COSV52968684; called by muse, mutect2, varscan2
- OR51B6 | c.632T>A p.I211N | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV66512683; called by muse, mutect2, varscan2
- OR52B4 | c.711C>G p.H237Q | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV68768759; called by muse, mutect2
- OR6K6 | c.578C>T p.T193I (on ENST00000368144; = p.T169I on NM_001005184.1) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs377139064, COSV63744902; called by muse, mutect2, varscan2
- PC | c.2220C>G p.I740M | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58992413; called by muse, mutect2, varscan2
- PCDH10 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52086817, COSV52091113; called by muse, mutect2, varscan2
- PCDH12 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51520660; called by muse, mutect2, varscan2
- PCDHGA2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.219); catalogued as COSV53925127; called by muse, mutect2, varscan2
- PCDHGA8 | c.2083G>A p.V695M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV53925136; called by muse, mutect2, varscan2
- PCM1 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1265187747, COSV61515624; called by muse, mutect2, varscan2
- PFKFB3 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs763367903, COSV57989828, COSV57993956; called by muse, mutect2, varscan2
- PIK3R1 | c.827C>G p.S276* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99141138; called by muse, mutect2, varscan2
- PKN2 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV60130841; called by muse, mutect2, varscan2
- PLEKHN1 | c.649G>C p.E217Q (on ENST00000379409; = p.E177Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58021442; called by muse, mutect2, varscan2
- POLR3A | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as COSV64930737; called by muse, mutect2, varscan2
- POM121L12 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs774741401, COSV68692615; called by muse, mutect2, varscan2
- PPP3CA | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV59921721; called by muse, mutect2, varscan2
- PRKAA2 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64803128; called by muse, mutect2, varscan2
- PSMB5 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57800329; called by muse, mutect2, varscan2
- PTCH1 | c.2315G>A p.R772K | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV59469246; called by muse, mutect2, varscan2
- RANBP6 | c.269C>G p.P90R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52388881; called by muse, mutect2, varscan2
- RAPGEF2 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52426498; called by muse, mutect2, varscan2
- RBP1 | c.55G>A p.E19K (on ENST00000619087 / NM_001365940.2; = p.E81K on NM_002899.5) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV51676184; called by muse, mutect2, varscan2
- RELN | c.5934C>G p.I1978M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV58994771; called by muse, mutect2, varscan2
- RNF111 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 168/287 reads (59%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV62084870; called by muse, varscan2
- RP9 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV51806451; called by muse, mutect2, varscan2
- RTN4 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV58266254; called by muse, mutect2, varscan2
- SACM1L | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV66612930; called by muse, mutect2, varscan2
- SAMD4B | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 188/373 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58750923; called by muse, mutect2, varscan2
- SAMD4B | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1414094566, COSV58750930; called by muse, mutect2, varscan2
- SCAF11 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1312683291, COSV56977100; called by muse, mutect2, varscan2
- SEC31B | c.3072G>A p.M1024I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV64844074; called by muse, mutect2, varscan2
- SH3GL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV53656615; called by muse, mutect2, varscan2
- SIRPB2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV63123446; called by muse, mutect2, varscan2
- SKA3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs754810578, COSV53434362; called by muse, mutect2, varscan2
- SLC45A4 | c.1327G>A p.A443T (on ENST00000517878 / NM_001286646.2; = p.A392T on NM_001080431.2) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as rs1489563197; called by muse, mutect2
- SMARCA4 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs752264295, COSV60790932; called by muse, mutect2, varscan2
- SNAI1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV54863804; called by muse, mutect2, varscan2
- SNTA1 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV54128790; called by muse, mutect2, varscan2
- SOAT1 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV62653588; called by muse, mutect2, varscan2
- SPEN | c.5818G>A p.E1940K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs755331266, COSV65360138; called by muse, mutect2, varscan2
- SPHKAP | c.3262G>C p.E1088Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60874378, COSV60898955; called by muse, mutect2, varscan2
- STAB1 | c.3285G>C p.Q1095H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV58734354; called by muse, mutect2, varscan2
- STS | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV54267355; called by muse, mutect2, varscan2
- SUOX | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV56267664; called by muse, mutect2, varscan2
- SYNC | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV65130147; called by muse, varscan2
- SYNC | c.1274del p.R425Kfs*17 | Frame Shift Del (DEL) | VAF 24/140 reads (17%) | catalogued as COSV65130153; called by pindel, varscan2
- TAB3 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.84); PolyPhen benign (0.175); catalogued as COSV55835678; called by muse, mutect2, varscan2
- TBX2 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.39); catalogued as rs749180743, COSV53598327; called by muse, mutect2, varscan2
- TG | c.8085G>C p.E2695D | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs756459399, COSV55071468; called by muse, mutect2, varscan2
- TMX4 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55680262; called by muse, mutect2, varscan2
- TNNI1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757767988, COSV60189136; called by muse, mutect2, varscan2
- TOB1 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.505); catalogued as rs775919369, COSV52150009; called by muse, mutect2, varscan2
- TPP2 | c.2927C>G p.S976* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV101060310; called by muse, mutect2, varscan2
- TPPP3 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 172/268 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52083709; called by muse, mutect2, varscan2
- TRIM51 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as COSV55265486, COSV55266209; called by muse, mutect2, varscan2
- TRIO | c.7994G>A p.G2665E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.96); catalogued as rs1372320588, COSV59989645; called by muse, mutect2, varscan2
- TRPA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/109 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51558957; called by muse, mutect2, varscan2
- TTLL10 | c.828G>T p.Q276H (on ENST00000379289 / NM_001130045.2; = p.Q203H on NM_153254.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV64959790, COSV64960665; called by muse, mutect2, varscan2
- TTLL8 | c.1201A>C p.I401L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56724308; called by muse, mutect2, varscan2
- TTN | c.81340G>A p.D27114N (on ENST00000591111; = p.D19690N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | PolyPhen benign (0.372); catalogued as COSV59976258; called by muse, mutect2, varscan2
- ULK1 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV58855773; called by muse, mutect2, varscan2
- UNC13C | c.4606C>T p.P1536S | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52859371; called by muse, mutect2, varscan2
- USP35 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.82); PolyPhen benign (0.092); catalogued as COSV71572691; called by muse, mutect2, varscan2
- VEZF1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV51967882; called by muse, mutect2, varscan2
- YTHDF2 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65723047; called by muse, mutect2, varscan2
- ZMYM3 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV58737108; called by muse, mutect2, varscan2
- ZNF251 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV52956815, COSV52959249; called by muse, mutect2, varscan2
- ZNF407 | c.4252G>C p.D1418H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55248333; called by muse, mutect2, varscan2
- ZNF536 | c.2875C>G p.P959A | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62821879; called by muse, mutect2
- ZNF548 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 180/636 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV60240733; called by muse, mutect2, varscan2
- ZNF585B | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100459335; called by muse, mutect2, varscan2
- ZNF799 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV70122246; called by muse, mutect2, varscan2
- ZNF846 | c.1556C>G p.S519* | Nonsense Mutation (SNP) | VAF 46/179 reads (26%) | catalogued as COSV67412457; called by muse, mutect2, varscan2
- BEND6 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- CASP9 | c.869-1G>C p.X290_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- CEP70 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 126/404 reads (31%) | called by muse, mutect2, varscan2
- FOXQ1 | c.318_319dup p.E107Afs*35 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | called by mutect2, varscan2
- HERC5 | c.2349del p.A784Pfs*23 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- HLA-DQA1 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA3 | c.861_865del p.P288* | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- IMMT | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- INO80E | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LIMK1 | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- MLLT6 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOP56 | c.264_267delinsTAA p.K88Nfs*21 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by pindel, varscan2*
- NTN1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR3A | c.3895G>T p.E1299* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PTN | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- RBL2 | c.1081del p.E361Kfs*9 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- SCAF1 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SULF1 | c.1787del p.G596Afs*19 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.462_472delinsGT p.T155_R158delinsC | In Frame Del (DEL) | VAF 17/44 reads (39%) | called by pindel, varscan2*
- ZBTB9 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- ZNF784 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2
- ABCA13 | c.7377T>C p.F2459= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV71285338; called by muse, mutect2, varscan2
- ACOT13 | c.422G>A p.*141= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs555358026, COSV57765594; called by muse, mutect2, varscan2
- ACTN2 | c.1392C>T p.I464= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs764086805, COSV63971447, COSV63972072; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRB1 | c.3051C>T p.F1017= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV60103623; called by muse, mutect2
- ADGRB2 | c.2148G>A p.L716= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV57072359; called by muse, mutect2, varscan2
- AGBL1 | c.561C>T p.Y187= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs371409529, COSV69796416; called by muse, mutect2, varscan2
- AP1M1 | c.594C>T p.I198= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- C11orf49 | c.995G>A p.*332= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as COSV53569601; called by muse, mutect2, varscan2
- C1QB | c.394C>T p.L132= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV59245195; called by muse, mutect2, varscan2
- CABIN1 | c.2667C>A p.L889= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV54080092; called by muse, mutect2, varscan2
- CELA2B | c.399C>T p.L133= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs200820219, COSV65545418; called by muse, mutect2, varscan2
- CHRNA10 | c.1287C>T p.F429= | Silent (SNP) | VAF 52/73 reads (71%) | catalogued as COSV51703784; called by muse, mutect2, varscan2
- COL14A1 | c.192G>A p.V64= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV52851165; called by muse, mutect2, varscan2
- CST9L | c.75G>A p.L25= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV65407749; called by muse, mutect2, varscan2
- DBX1 | c.351C>T p.S117= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57053826; called by muse, mutect2, varscan2
- DENND2A | c.666G>A p.L222= | Silent (SNP) | VAF 53/194 reads (27%) | catalogued as COSV52049584; called by muse, mutect2, varscan2
- EIF4G3 | c.709C>T p.L237= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV51679001; called by muse, mutect2, varscan2
- EPS8L1 | c.1230G>A p.P410= (on ENST00000201647 / NM_133180.3; = p.P283= on NM_017729.3) | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV52381260; called by muse, mutect2, varscan2
- FAM110A | c.321C>T p.L107= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1052034590; called by muse, mutect2, varscan2
- GNB1L | c.468G>A p.P156= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs765510974, COSV61547521, COSV61548274, COSV61549670; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPRC5C | c.444C>T p.L148= (on ENST00000652232; = p.L103= on NM_018653.4) | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs148101331; called by muse, mutect2, varscan2
- H1-2 | c.264G>A p.V88= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as rs939053331, COSV59190236; called by muse, mutect2, varscan2
- HGF | c.1143A>G p.P381= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1307541359, COSV55947437; called by muse, mutect2, varscan2
- HIF1A | c.1914G>A p.L638= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV60188768; called by muse, mutect2, varscan2
- KCNN3 | c.1528C>T p.L510= (on ENST00000618040 / NM_001204087.1; = p.L495= on NM_002249.6) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV55214751; called by muse, mutect2, varscan2
- KIAA1522 | c.1800C>T p.V600= (on ENST00000373480 / NM_001198972.2; = p.V659= on NM_020888.3) | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as COSV53863525, COSV99615070; called by muse, mutect2, varscan2
- MAST4 | c.3564G>A p.L1188= (on ENST00000403625 / NM_001164664.2; = p.L999= on NM_015183.3) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV55120818; called by muse, mutect2, varscan2
- MMP21 | c.150C>G p.L50= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV64289140; called by muse, mutect2, varscan2
- MRGPRE | c.240C>T p.I80= | Silent (SNP) | VAF 66/98 reads (67%) | catalogued as rs369200596; called by muse, mutect2, varscan2
- MVK | c.651T>C p.H217= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as COSV57331603; called by muse, mutect2
- MYF5 | c.369C>T p.I123= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as COSV57354828, COSV57356142; called by muse, mutect2, varscan2
- NT5DC2 | c.1335C>T p.F445= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs776498961, COSV58734355; called by muse, mutect2, varscan2
- NUP43 | c.1059G>A p.V353= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100461943, COSV61189267; called by muse, mutect2, varscan2
- OR10S1 | c.159T>G p.A53= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV73342730; called by muse, mutect2, varscan2
- OR5L1 | c.681G>A p.K227= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV61733372; called by muse, mutect2, varscan2
- PDE4A | c.651C>T p.V217= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV53353104; called by muse, mutect2, varscan2
- PLXND1 | c.3705G>A p.S1235= | Silent (SNP) | VAF 121/291 reads (42%) | catalogued as rs762034293, COSV60710845, COSV60719044; called by muse, mutect2, varscan2
- PRKD2 | c.237G>A p.Q79= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as COSV52185682; called by muse, mutect2, varscan2
- PUS1 | c.843G>C p.V281= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as rs765187140, COSV59035090; called by muse, mutect2, varscan2
- PUS1 | c.1173G>C p.L391= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV59035099; called by muse, mutect2, varscan2
- PZP | c.1152G>C p.V384= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV54357660; called by muse, mutect2, varscan2
- RP1L1 | c.4848C>T p.L1616= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV101222846, COSV66753711; called by muse, varscan2
- RPRD1B | c.63G>A p.Q21= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV65032588; called by muse, mutect2, varscan2
- RSPH14 | c.696C>T p.V232= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV53267783; called by muse, mutect2, varscan2
- RYR1 | c.4653C>T p.V1551= | Silent (SNP) | VAF 95/181 reads (52%) | catalogued as COSV62093952; called by muse, mutect2, varscan2
- SH3GL1 | c.444G>A p.E148= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV53656620; called by muse, mutect2, varscan2
- SLC12A4 | c.732G>T p.S244= | Silent (SNP) | VAF 43/61 reads (70%) | catalogued as rs372226074, COSV57927750; called by muse, mutect2, varscan2
- SLC6A13 | c.708C>T p.F236= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV58256488; called by muse, mutect2, varscan2
- SMYD4 | c.1335C>G p.L445= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV59711221; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3456G>A p.K1152= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV59128759; called by muse, mutect2
- SULF2 | c.759G>A p.A253= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs536732621, COSV63415176; called by muse, mutect2, varscan2
- SUPT20H | c.2154G>A p.Q718= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV53508884; called by muse, mutect2, varscan2
- SUV39H2 | c.810G>A p.K270= (on ENST00000354919 / NM_001193424.2; = p.K210= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV57953382; called by muse, mutect2, varscan2
- TCTA | c.294C>G p.L98= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1361140974, COSV55534004; called by muse, mutect2, varscan2
- TIMD4 | c.273G>A p.P91= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs774244018, COSV50854024, COSV99192883; called by muse, mutect2, varscan2
- TMEM145 | c.1311C>T p.F437= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs762906371, COSV52080192; called by muse, mutect2, varscan2
- TMEM150B | c.657C>T p.L219= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100442287; called by muse, mutect2, varscan2
- TMEM270 | c.63C>G p.L21= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TNIK | c.135C>G p.V45= | Silent (SNP) | VAF 88/135 reads (65%) | catalogued as COSV52678630; called by muse, mutect2, varscan2
- TRPV2 | c.903C>T p.A301= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1234105711, COSV58427918; called by muse, mutect2, varscan2
- UBE2O | c.3033C>T p.I1011= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1262584248, COSV60061859; called by muse, mutect2, varscan2
- UBN1 | c.414C>T p.F138= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV52167200; called by muse, mutect2, varscan2
- USP15 | c.2631G>C p.L877= (on ENST00000280377 / NM_001351159.2; = p.L848= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54790294; called by muse, mutect2, varscan2
- UTRN | c.6408C>G p.L2136= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100839544, COSV62331417; called by muse, mutect2, varscan2
- VDAC1 | c.210G>A p.T70= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs201680896; called by muse, mutect2, varscan2
- ZNF358 | c.1170C>A p.L390= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV51174604; called by muse, mutect2, varscan2
- ZNF479 | c.462C>T p.N154= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV58637064, COSV58637468; called by muse, mutect2, varscan2
- ZP4 | c.147A>G p.A49= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV63911614; called by muse, mutect2, varscan2
- ACACB | c.6497-343G>A | Intron (SNP) | VAF 49/321 reads (15%) | catalogued as COSV58131591; called by muse, mutect2, varscan2
- KCNC4 | c.*648C>G | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as COSV63925413; called by muse, varscan2
- KDM2B | c.*147C>T | 3'UTR (SNP) | VAF 26/133 reads (20%) | catalogued as rs782116976, COSV65639394; called by muse, varscan2
- NOP56 | c.570-127G>C | Intron (SNP) | VAF 51/112 reads (46%) | catalogued as COSV100249995; called by muse, mutect2, varscan2
- SSPOP | n.1022G>C | RNA (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- VPS11 | c.-180G>A | 5'UTR (SNP) | VAF 39/54 reads (72%) | called by muse, mutect2, varscan2
- ZNF157 | c.*2G>A | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100998459; called by muse, mutect2, varscan2
- ZNF783 | c.802+3058G>T | Intron (SNP) | VAF 26/74 reads (35%) | catalogued as COSV65185078; called by muse, mutect2, varscan2
- ZNF783 | c.802+3059G>T | Intron (SNP) | VAF 26/76 reads (34%) | catalogued as COSV65185083; called by muse, mutect2, varscan2
